Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J4, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J4-01A (Primary Tumor).

ICD-0-3
Carcinoma, adrenal cortical
8370/3
Site: (B) Adrenal Gland
Cortex C74.0
Jt) 1/25/13

One vessel containing a material immersed in formaldehyde solution, described as following: product of a right adrenal mass resection, weighting 555 g and measuring 14.5 x 11.5 x 6.5 cm, previously sectioned. The external surface is light brown and irregularly shaped. The internal surface of the mass is characterized by a friable and multilobulated light brown tissue, with yellow nodules (largest nodule measures 2 cm). Few hemorrhagic areas are evident.

Product of right adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 14 cm.
- Weight – 117 g
- Nuclear grade (Fuhrman) – high
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – not detected
- Areas of necrosis – present
- Mitotic count – >5 in 50 H.P.F.
- Atypical mitosis – present
- Capsular invasion – not detected
- Venous invasion – present

[illegible]

Source: NCI Genomic Data Commons file fba50a9b-4a90-4381-9a48-24c4f4b04e2e (TCGA-OR-A5J4.39E300DC-C01F-46BC-AE4C-D834458F1FF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).